Surgical pathology report (de-identified scan), TCGA case TCGA-86-8669, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8669-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]		Case ID	Gross Description	Microscopic Description	Diagnosis Details
[REDACTED]		[REDACTED]	???? ?????? ?????????? ??? ????????? ???-????????? ??? ?? ??????, ????? ? ????????? - ?????? ??????-????? ????? ????? ? ????????? ?????????.	????????? ??????? ?? ?? ????????? ????????????? , ?????????? ?????????? ?? ??????????. ?????? ?? ??????, ??? ?? ????? ???, ?????? ????????? ????????? .	T????????? ????? ????????? ?????? ? .

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 3 x 2.5 x 2 cm Histologic type: Adenocarcinoma Histologic grade: Well differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified

ica ID

[page 3 of 3]
Excision date

--

Source: NCI Genomic Data Commons file 4cbaaa6d-943d-41a2-9391-547121a6e71b (TCGA-86-8669.6C8D6319-A235-4757-BE34-79286A8DA60F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).